Surgical pathology report (de-identified scan), TCGA case TCGA-06-A7TK, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A7TK-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken: .
DOB: (Age: Location: Received:
Gender: M Accnt: Reported:
Physician(s):
Phy Location: .

Clinical History

year-old man experiences headaches and change in mental status. On imaging, there is a large, cystic and necrotic, ring-enhancing tumor in the right frontal lobe extending to the basal ganglia, external capsule and temporal lobe.

Operative Diagnoses

Brain lesion

Operation / Specimen

- A: Brain, right frontal tumor, biopsy
- B: Brain, right frontal tumor, biopsy
- C: Brain, right frontal enhancing tumor, excision biopsy

Pathologic Diagnosis

A, B and C. Brain, right frontal, excisional biopsies: Glioblastoma (WHO 4).

- 1. 1p, 19q LOH (codeletion): Negative.
- 2. IDH1-R132H mutant protein: Negative.
- 3. MGMT: Positive.
- 4. MIB-1 proliferation index: 42%.

See Microscopy Description and Comment.

Comment

The sections contain portions of cerebrum that are infiltrated and effaced by an astrocytic neoplastic proliferation that has nuclear anaplasia, brisk mitotic activity with a MIB-1 proliferation index of about 42%, prominent microvascular cellular proliferation, and zones of tumor necrosis, some with pseudopalisading. The features are those of a glioblastoma (WHO 4).

Electronically Signed Out

Consultant: M.D., Senior Staff Pathologist
MD, Senior Staff Pathologist

Procedures/Addenda

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: Date Reported:

Surgical Pathology

Page 2 of 3

Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

Allelic loss on chromosome arm 1p is NOT detected (negative for loss of heterozygosity on chromosome arm 1p)

Informative loci are: D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (B1). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and tumor DNA was enriched by microdissection

ICD O-3
Glioblastoma multiforme 9440/3
Site @ Brain, frontal lobe
C71.1
JJD 9/26/13

[page 2 of 3]
TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (B1)

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

Surgical Pathology

Page 3 of 3

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug

[page 3 of 3]
Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A.

Brain, right frontal tumor, biopsy: High histological grade glioma (C/W glioblastoma). Touch preparation

smears performed at and results reported to the

M.D., Senior

Staff Pathologist

Gross Description

A.

Brain, right frontal tumor, biopsy:

CONTAINER LABEL: right frontal tumor.

FIXATIVE: Formalin. NO. PIECES: multiple. SIZE/VOL: gray-white soft focally hemorrhagic tissue 2 x 1 x 0.3 cm.

CASSETTES: 1,

B.

Brain, right frontal tumor, biopsy:

CONTAINER LABEL: right frontal tumor.

FIXATIVE: Formalin. NO. PIECES: few. SIZE/VOL: dusky red to gray white soft tissue fragments 1 x 1 x 0.5 cm.

CASSETTES: 1,

C.

Brain, right frontal enhancing tumor, excision biopsy:

CONTAINER LABEL: right frontal enhancing tumor.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 2.5 x 1.5 x 1 cm irregular pink-tan gelatinous focally hemorrhagic

soft tissue fragment. CASSETTES: 2,

Microscopic Description

IMMUNOHISTOCHEMISTRY: The neoplastic cells are not reactive with IDH1-R132H antiserum. With the MIB-1

there is a proliferation index of 42% throughout.

ICD-9(s): 191.9 191.9

Billing Fee Code(s): A:

B:

C:

LOH 1p19q:

MGMT:

Case is (Single):	QUALIFIED	UNQUALIFIED
Reviewed/Initiated:	9/10/13	

Source: NCI Genomic Data Commons file 72dd346d-1880-4cf1-9600-f39775e813c8 (TCGA-06-A7TK.5A1F6CD8-15C3-4D80-8496-340B0A9616D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).